Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4945, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4945-01A (Primary Tumor).

FINAL DIAGNOSIS:**KIDNEY, RIGHT, RADICAL NEPHRECTOMY-**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR AND GRANULAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 2 OF 4.
- B. THE GREATEST DIAMETER OF THE NEOPLASM IS 4.0 CM.
- C. THE NEOPLASM IS CONFINED TO THE KIDNEY WITHOUT EXTRACAPSULAR EXTENSION, NOR INVOLVEMENT OF THE RENAL PELVIS/RENAL SINUS.
- D. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. SEPARATE SMALL PAPILLARY RENAL TUBULAR EPITHELIAL NEOPLASM OF LOW MALIGNANT POTENTIAL (ADENOMA, SLIDE F).
- F. THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL GLOBAL GLOMERULOSCLEROSIS INVOLVING 5-10% OF GLOMERULI, OTHERWISE IS UNREMARKABLE.
- G. BENIGN PROXIMAL URETER AND PERI-RENAL ADIPOSE TISSUE.
- H. TNM STAGE: pT1a Nx MX.
- I. TNM HISTOLOGIC GRADE = G2.

Source: NCI Genomic Data Commons file 795d7ce6-31e8-4b79-bb70-79cdff6ec351 (TCGA-B0-4945.8478C195-E08D-40CD-9103-6EF991AC4C3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).